Surgical pathology report (de-identified scan), TCGA case TCGA-CJ-4876, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CJ-4876-01A (Primary Tumor).

Pathology Report

DIAGNOSIS

(A) LEFT KIDNEY AND ADRENAL GLAND:

RENAL CELL CARCINOMA, CONVENTIONAL (70% CLEAR CELLS AND 30% EOSINOPHILIC CELLS),

FUHRMAN'S NUCLEAR GRADE 3. (SEE COMMENT)

NO EXTENSION INTO THE PERINEPHRIC ADIPOSE TISSUE.

TUMOR MEASURES 10.5 CM IN MAXIMUM DIMENSION.

Ureteral and vascular margins of resection, free of tumor.

Adrenal gland, no tumor present.

COMMENT

The tumor focally bulges into the renal sinus adipose tissue but does not infiltrate it.

GROSS DESCRIPTION

(A) LEFT KIDNEY AND ADRENAL GLAND - A nephrectomy specimen (23.5 x 15.0 x 6.8 cm), including the kidney (13.5 x 5.0 x 5.0 cm), attached segment of unremarkable ureter (15.0 cm in length and 0.5 cm in diameter) and attached unremarkable previously opened adrenal gland (6.5 x 1.5 x 0.3 cm).

A well-circumscribed tan-yellow tumor with central gelatinous areas, focal calcification and hemorrhage is present in the lower pole of the kidney (10.5 x 9.0 x 5.5 cm) compressing the normal parenchyma and pushing into the peri-nephric fat. However, the tumor is limited by the capsule. The tumor is 5.0 cm away from the upper pole and 7.0 cm from the adrenal glands. The tumor is close, but does not grossly involve the pelvis, calyx or renal vein.

The pelvis, calyx, and ureter are not dilated. The remaining renal parenchyma is unremarkable. The adrenal gland is previously opened and unremarkable.

INK CODE: black, external surface of the specimen close to the tumor.

SECTION CODE: A1, ureteral resection margin; A2, vascular resection margins at hilum, A3-A5, tumor with adjacent pelvis and calyx, and renal vein; A6, tumor with calyx; A7, tumor with closest serosal surface; A8, tumor; A9, tumor with adjacent normal kidney and perinephric fat; A10, A11, tumor with perinephric fat; A12, tumor with adjacent kidney; A13, adrenal gland; A14, unremarkable kidney.

CLINICAL HISTORY

Left renal mass.

SNOMED CODES

T-71000, M-83123

Source: NCI Genomic Data Commons file a3af9e34-2093-447e-939d-20718c4c32c9 (TCGA-CJ-4876.9EDA680F-4409-4FEE-8051-D546119E4F41.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).